Somatic mutation profile of tumor specimen BA2812D (aliquot aq-BA2812D) from BEATAML1.0 case 2563, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed phenotype acute leukemia, T/myeloid, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.1 years (16,824 days).
Specimen BA2812D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eec05c9c-996e-478d-8b06-ed0cea8bfb1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2384D (Solid Tissue Normal), aliquot aq-BA2384D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9ba0e1e-4902-454f-af1a-fc847fec948d

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SNRPB | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs750433171; called by muse, mutect2, varscan2
- STAG2 | c.3054-2A>C p.X1018_splice | Splice Site (SNP) | VAF 24/40 reads (60%) | catalogued as COSV54374307; called by muse, varscan2
- ADSS2 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1QC | c.679A>G p.M227V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- AC114490.3 | c.*694G>T | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- CABCOCO1 | c.-15T>C | 5'UTR (SNP) | VAF 34/117 reads (29%) | called by muse, mutect2, varscan2
- NYNRIN | c.*897A>G | 3'UTR (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
